Somatic mutation profile of tumor specimen MBCProject_6136_T1_WES (aliquot MBCProject_6136_T1_WES_1) from CMI case MBCProject_6136, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 64.3 years (23,502 days).
Specimen MBCProject_6136_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d855426-01fe-477e-a22a-0b7247588f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_6136_SALIVA (Saliva), aliquot MBCProject_6136_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da5caf10-1577-4a62-b2e7-9cb3d0e078ca

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 262/528 reads (50%) | catalogued as rs730882131, COSV64294889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDCP2 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as rs1039433184; called by muse, mutect2, varscan2
- DHX57 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs138902985; called by muse, mutect2, varscan2
- DNER | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 106/470 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs530602445, COSV59160424; called by muse, mutect2, varscan2
- FAM200B | c.773dup p.L258Ffs*28 | Frame Shift Ins (INS) | VAF 33/156 reads (21%) | catalogued as rs1251004707; called by mutect2, pindel, varscan2
- KDM5B | c.3139C>G p.R1047G | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs750775126, COSV52512284, COSV99351202; called by muse, mutect2
- LINGO2 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58060155, COSV58063806; called by muse, mutect2, varscan2
- PLEC | c.4909C>T p.R1637W (on ENST00000322810 / NM_201380.4; = p.R1527W on NM_000445.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781942131; called by muse, mutect2, varscan2
- PRAMEF11 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 167/665 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1389971277; called by muse, mutect2, varscan2
- SCN10A | c.4979C>T p.S1660L | Missense Mutation (SNP) | VAF 105/484 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998456008, COSV71861374; called by muse, mutect2, varscan2
- SLC22A23 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV66675459; called by muse, mutect2, varscan2
- SLC23A2 | c.1526T>C p.I509T | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs886455107; called by muse, mutect2, varscan2
- SLC35B2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs1432821201; called by muse, mutect2, varscan2
- TBX3 | c.972dup p.F325Vfs*2 (on ENST00000257566 / NM_016569.4; = p.F305Vfs*2 on NM_005996.4) | Frame Shift Ins (INS) | VAF 242/875 reads (28%) | catalogued as COSV99983262; called by mutect2, pindel, varscan2
- ZHX2 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 145/379 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs878941980; called by muse, mutect2, varscan2
- ZHX2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 142/375 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV58713229; called by muse, mutect2, varscan2
- ZMYM6 | c.426G>A p.S142= | Splice Region (SNP) | VAF 88/352 reads (25%) | catalogued as rs146406265; called by muse, mutect2, varscan2
- AMPD3 | c.500G>A p.R167Q (on ENST00000396553 / NM_001025389.2; = p.R176Q on NM_000480.3) | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BHLHE40 | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 90/353 reads (25%) | called by muse, mutect2, varscan2
- C6orf141 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); called by muse, mutect2
- FKBP11 | c.440A>C p.N147T | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, varscan2
- GOLGB1 | c.6836G>T p.C2279F | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- NCOA6 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 81/273 reads (30%) | called by muse, mutect2, varscan2
- SHD | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132D | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP1B3 | c.147C>T p.F49= | Silent (SNP) | VAF 164/428 reads (38%) | catalogued as COSV53951025; called by mutect2, varscan2
- DOCK4 | c.3384C>G p.R1128= | Silent (SNP) | VAF 84/385 reads (22%) | catalogued as rs1472305166; called by muse, mutect2, varscan2
- DTX1 | c.708G>A p.P236= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1162565240; called by muse, mutect2, varscan2
- HPS4 | c.693C>T p.A231= | Silent (SNP) | VAF 142/570 reads (25%) | catalogued as COSV61102861; called by muse, mutect2, varscan2
- MAP7D2 | c.1203G>A p.A401= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as rs1213837789, COSV65526604; called by muse, mutect2, varscan2
- MUC16 | c.14472G>A p.T4824= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs751538389, COSV67457476; called by muse, mutect2, varscan2
- PRDX4 | c.213C>T p.D71= | Silent (SNP) | VAF 56/204 reads (27%) | called by muse, mutect2, varscan2
- UBR5 | c.5556A>G p.Q1852= | Silent (SNP) | VAF 86/468 reads (18%) | catalogued as rs763183966; called by muse, mutect2, varscan2
- C1orf21 | c.*1C>T | 3'UTR (SNP) | VAF 41/299 reads (14%) | catalogued as rs1472469482; called by muse, mutect2, varscan2
- GVINP1 | n.6549C>T | RNA (SNP) | VAF 13/69 reads (19%) | catalogued as rs1431880916; called by muse, mutect2, varscan2
- UBAC2 | c.31+604C>T | Intron (SNP) | VAF 74/247 reads (30%) | called by muse, mutect2, varscan2
